Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABK0, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABK0-TTP1-A (Primary Tumor).

HISTOPATHOLOGY EXAM

CDDP-YP-ABK0-01-PR

SPECIMEN RECEIVED

Upper right pulmonary lobe, excision

MACROSCOPIC DESCRIPTION

Pulmonary lobe measuring 7.5x10x4 cm, with smooth and shiny visceral pleura. On cutting, in the parenchyma adjacent to the lobar bronchus, there is a whitish hard-elastic neoformation with indistinct margins, measuring 3.2 cm along the main axis, which creates a 2.5 cm long sleeve around the bronchial wall, resulting in the stenosis of the lumen. The neoformation reaches near the bronchial resection margin at 1 cm distance from the visceral pleura. Intraoperative exam performed on the bronchial margin.

(A1 intraoperative exam; A2 vascular margin and hilar lymph nodes; A3 section parallel to the bronchial margin; A4-A6 neoplasia; A7-A8 neoplasia-visceral pleura; A9 non-neoplastic parenchyma).

HISTOPATHOLOGICAL DIAGNOSIS

Medium-differentiated (G2), extensively necrotic acinar-type pulmonary adenocarcinoma (WHO). Presence of peritumoral vascular invasion and perineural infiltration. The visceral pleura and the bronchial resection margin are free of neoplastic infiltration. Focal edema, atelectasis and bleeding in the rest of the parenchyma. Lymphnodal metastasis of adenocarcinoma in 1 of 3 tested peribronchial lymph nodes.

Stage pTNM: pT2, N1

Intraoperative exam
Special staining: Alcian PAS:

Bronchial margin free of neoplasia.

(See tests

).

SNOMED codes:

T-28200 M-81403

T-28000 M-09410

F-D002

ICD-0-3

adenocarcinoma, acinar 8550/3

Site: (R) lung, upper lobe C34.1

page 1 of 2

ICD-10

C34.11

lw
2/9/16

page 2 of 2

Source: NCI Genomic Data Commons file 60b34039-aed6-484a-bac6-ba6e30672991 (CDDP-ABK0-TTP1.5ED55A3A-95BC-4506-BEA2-A3018124EB82.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).